Somatic mutation profile of tumor specimen MBCProject_3521_T1_WES (aliquot MBCProject_3521_T1_WES_1) from CMI case MBCProject_3521, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 64.8 years (23,668 days).
Specimen MBCProject_3521_T1_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Breast; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 75aac3e7-69e2-4570-97d2-5e53369b2130.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_3521_SALIVA (Saliva), aliquot MBCProject_3521_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8fd7dc7a-0234-4bec-badf-ef22982c8317

The open-access MAF lists 39 somatic variants for this specimen: 10 protein-altering or splice-affecting, 6 silent, 23 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Intron 17, Missense Mutation 8, Silent 6, RNA 3, 3'UTR 2, Splice Region 1, Nonstop Mutation 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EFCAB2 | c.810A>G p.*270Wext*5 (on ENST00000366522; = p.*134Wext*5 on NM_001143943.1) | Nonstop Mutation (SNP) | VAF 13/82 reads (16%) | catalogued as rs1218866620, COSV63659826; called by muse, varscan2
- ELF3 | c.1109G>A p.R370Q | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.007); catalogued as rs768235554; called by mutect2, varscan2
- NIPBL | c.5027A>G p.Y1676C | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs559139612; called by mutect2, varscan2
- NOTCH1 | c.474C>G p.F158L | Missense Mutation (SNP) | VAF 20/186 reads (11%) | SIFT tolerated (0.46); PolyPhen benign (0.046); catalogued as rs774011231; called by muse, mutect2, varscan2
- PKP2 | c.1460A>G p.Q487R | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0); catalogued as rs778247181, COSV50726138; ClinVar: uncertain significance; called by mutect2, varscan2
- YBX1 | c.167-8T>G | Splice Region (SNP) | VAF 12/83 reads (14%) | catalogued as rs1212004761; called by muse, mutect2, varscan2
- ARPP21 | c.658A>G p.I220V | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.579); called by muse, mutect2
- HNRNPA2B1 | c.326T>C p.V109A (on ENST00000354667 / NM_031243.3; = p.V97A on NM_002137.4) | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0.264); called by muse, mutect2
- HTR3D | c.1033C>T p.L345F (on ENST00000382489 / NM_001163646.2; = p.L170F on NM_182537.3) | Missense Mutation (SNP) | VAF 18/160 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.737); called by muse, mutect2
- ITGA10 | c.2659G>A p.G887R | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.38); PolyPhen benign (0.021); called by mutect2, varscan2
- DPY19L3 | c.321C>T p.L107= | Silent (SNP) | VAF 10/84 reads (12%) | catalogued as rs557500437, COSV60479980; called by mutect2, varscan2
- ELAPOR1 | c.1641G>A p.T547= | Silent (SNP) | VAF 6/54 reads (11%) | catalogued as rs764038930; called by mutect2, varscan2
- EPHA1 | c.1731G>A p.R577= | Silent (SNP) | VAF 11/79 reads (14%) | called by muse, mutect2
- FSHR | c.318C>T p.N106= | Silent (SNP) | VAF 16/154 reads (10%) | catalogued as COSV58622481; called by muse, mutect2
- KCNMB2 | c.372G>A p.G124= | Silent (SNP) | VAF 5/43 reads (12%) | catalogued as rs575957428; called by mutect2, varscan2
- NOM1 | c.2547G>A p.T849= | Silent (SNP) | VAF 6/62 reads (10%) | catalogued as rs781508051, COSV51979553; called by mutect2, varscan2
- AC108676.1 | n.203T>C | RNA (SNP) | VAF 8/42 reads (19%) | catalogued as rs1169048224; called by muse, mutect2
- AGBL3 | c.311-6971C>T | Intron (SNP) | VAF 12/58 reads (21%) | catalogued as rs1161122768; called by muse, mutect2
- AL033381.1 | n.448G>A | RNA (SNP) | VAF 4/39 reads (10%) | catalogued as rs973730013; called by mutect2, varscan2
- C5 | c.2563-2177A>G | Intron (SNP) | VAF 4/36 reads (11%) | catalogued as rs1351664110; called by mutect2, varscan2
- FXN | chr9:69035902 del T | 5'Flank (DEL) | VAF 14/76 reads (18%) | called by mutect2, pindel, varscan2
- GALNT13 | c.1396-964A>G | Intron (SNP) | VAF 6/58 reads (10%) | catalogued as rs1455810595; called by muse, varscan2
- GDA | c.578+821A>C | Intron (SNP) | VAF 6/28 reads (21%) | catalogued as rs375043152; called by muse, mutect2
- GP6 | c.*617T>C | 3'UTR (SNP) | VAF 16/222 reads (7%) | called by muse, mutect2
- LACTB2 | c.286+919C>A | Intron (SNP) | VAF 8/65 reads (12%) | catalogued as rs1480173173, COSV52570280; called by muse, varscan2
- LINC01549 | n.373A>G | RNA (SNP) | VAF 9/75 reads (12%) | called by mutect2, varscan2
- MAP3K15 | c.1749-1263A>C | Intron (SNP) | VAF 7/40 reads (18%) | catalogued as rs1307001562; called by muse, mutect2
- MATR3 | c.*1448A>G | 3'UTR (SNP) | VAF 10/45 reads (22%) | catalogued as rs1298787056; called by muse, varscan2
- NASP | c.60-2535dup | Intron (INS) | VAF 4/25 reads (16%) | catalogued as rs1415971471; called by pindel, varscan2
- NLRP2 | c.281-393A>G | Intron (SNP) | VAF 6/36 reads (17%) | catalogued as rs752108162; called by mutect2, varscan2
- POLA1 | c.2947-20889C>G | Intron (SNP) | VAF 10/66 reads (15%) | called by mutect2, varscan2
- POLR2C | c.136+613T>C | Intron (SNP) | VAF 8/77 reads (10%) | called by muse, mutect2
- PRRG1 | c.172-12259T>C | Intron (SNP) | VAF 8/46 reads (17%) | called by muse, mutect2
- RNF4 | c.125-1317G>A | Intron (SNP) | VAF 16/86 reads (19%) | catalogued as rs1319401008; called by muse, varscan2
- SEPTIN9 | c.722-36732T>C | Intron (SNP) | VAF 6/64 reads (9%) | called by muse, mutect2, varscan2
- TERB1 | c.1996+61A>C | Intron (SNP) | VAF 8/68 reads (12%) | called by muse, varscan2
- TUBGCP2 | c.616+586A>G | Intron (SNP) | VAF 8/76 reads (11%) | called by mutect2, varscan2
- XPO5 | c.2678-356T>C | Intron (SNP) | VAF 17/120 reads (14%) | catalogued as rs1242378776, COSV54830476; called by muse, mutect2
- ZNF273 | c.326-4267T>C | Intron (SNP) | VAF 21/189 reads (11%) | called by muse, mutect2
